Surgical pathology report (de-identified scan), TCGA case TCGA-XE-A8H1, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-A8H1-01A (Primary Tumor).

[page 1 of 2]
Ord #=

RESULTED

Collect D/T=

SURGICAL PATHOL

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right testicle

Clinical History
Not stated

ICD O-3
Carcinoma, embryonal NOS 9070/3
Site ^{UAF} Testis NOS C62.9
path Testicle NOS C62.9
JW 11/24/13

Gross Description

Right testicle: Received fresh is a testicle weighing 75 grams and measuring overall 15 x 5 x 3 cm. The testis measures 6.5 x 5 x 3 cm. The spermatic cord measures 11 x 2 x 0.5 cm. The entire specimen is inked black. The tumor measures 3 x 2 x 2 cm and is firm tan with brown area. The remaining parenchyma is unremarkable. The tumor abuts the tunica albuginea, however, the tunica albuginea is not adherent to the tumor. Representative sections are submitted as follows:

- 1 spermatic cord margin
- 2 cord adjacent to margin (green) and mid cord section
- 3 epididymis
- 4-6 tumor
- 7 normal

Date of Dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis
Specimen Type: Right testicle
-Laterality: Right
-Focality: Multifocal

[page 2 of 2]
RESULTS FOR SELECTED GRID CELL, SUMMARY

- Tumor Size: 3 x 2 x 2 cm
- Histologic Type: Embryonal carcinoma, pure. (see comment)
- Intratubular germ cell neoplasia is present (slide 4).
- Tumor is limited to the testis. Tumor does not involve rete testis, epididymis, perihilar fat, spermatic cord, tunica vaginalis or scrotal wall.
- Lymphovascular Invasion: Present (slide 5).
- Margin: Spermatic cord is negative for tumor.
- Remaining testicular tissue shows tubular atrophy, and the epididymis normal and uninvolved by tumor.

Comment: Immunohistochemical stain was performed on slide 6 for pancytokeratin (AE1/AE3), CD30 and PLAP are positive on the critical cells; the PLAP stain shows membrane staining. Immunohistochemical stain for hCG is negative for syncytiotrophoblastic elements.
Pathologic Tumor Stage: pT2NXMX (Stage IS)

Attending Pathologist:

***Electronically Signed Out By

*** Note: Immunohistochemistry testing was developed and its performance characteristics determined by

. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigation or research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing. ***

Source: NCI Genomic Data Commons file a36ad556-6cdf-4d06-abd5-14385fb26250 (TCGA-XE-A8H1.7C060166-F812-47BB-94DF-E8E4A6800FEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).